TCGA case TCGA-55-6970 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7cce924f-12a1-4895-9866-5d4b1869dde6

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 464 days (1.3 years).

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.8 years (24,773 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Days to treatment start: 89 days; Days to treatment end: 117 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 90 days; Days to treatment end: 124 days; Treatment outcome: Stable Disease; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 162 days; Days to treatment end: 183 days; Treatment outcome: Stable Disease.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 69.1 years (25,230 days); Days to diagnosis: 457 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (2 entries)
- Day 457 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 457 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 464 days (1.3 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-55-6970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-55-6970-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
  Slide TCGA-55-6970-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-55-6970-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-55-6970-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.4; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Papillary Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Drug treatment 2: Pharmaceutical therapy drug name: VP-16.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 464 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 464 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 457 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-55-6970-01A-11D-1943-01): tumor purity 0.56, ploidy 1.36, whole-genome doublings 0.
